Somatic mutation profile of tumor specimen TCGA-DX-A48J-01A (aliquot TCGA-DX-A48J-01A-21D-A307-09) from TCGA case TCGA-DX-A48J, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 44.6 years (16,279 days).
Specimen TCGA-DX-A48J-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b7b3434d-d077-4de9-9b0b-47a1ede2cefa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DX-A48J-10A (Blood Derived Normal), aliquot TCGA-DX-A48J-10A-01D-A307-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f124db33-923c-40ff-8d55-de10f0e28903

The open-access MAF lists 12 somatic variants for this specimen: 10 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, RNA 1, Splice Site 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 16/18 reads (89%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- CCDC7 | c.3956C>T p.T1319I | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.867); catalogued as COSV100177338; called by muse, mutect2, varscan2
- DNAH3 | c.2650G>C p.E884Q | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.331); catalogued as COSV99764658; called by muse, mutect2, varscan2
- F5 | c.3371A>G p.E1124G | Missense Mutation (SNP) | VAF 43/105 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV100888848; called by muse, mutect2, varscan2
- GSTA4 | c.414+1G>T p.X138_splice | Splice Site (SNP) | VAF 88/107 reads (82%) | catalogued as COSV100919779; called by muse, mutect2, varscan2
- MYO3A | c.617C>T p.T206I | Missense Mutation (SNP) | VAF 31/49 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.58); catalogued as COSV99778047; called by muse, mutect2, varscan2
- RASAL2 | c.193C>T p.R65W | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.656); catalogued as COSV100862304; called by muse, mutect2, varscan2
- RETREG2 | c.667G>T p.V223L | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); catalogued as COSV99811340; called by muse, mutect2, varscan2
- SPPL2C | c.1807G>A p.G603S | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.044); catalogued as COSV100233914; called by muse, mutect2, varscan2
- TMEM132D | c.1331C>T p.T444M | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs771427502, COSV70606964; called by muse, mutect2, varscan2
- MCF2L | c.1155G>T p.A385= (on ENST00000375608; = p.A353= on NM_024979.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as COSV100982080; called by muse, mutect2, varscan2
- MIR200A | n.7C>T | RNA (SNP) | VAF 59/68 reads (87%) | called by muse, mutect2, varscan2
